Somatic mutation profile of tumor specimen TCGA-AG-A01N-01A (aliquot TCGA-AG-A01N-01A-01W-A00E-09) from TCGA case TCGA-AG-A01N, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.6 years (25,049 days).
Specimen TCGA-AG-A01N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44440bac-87c9-47cf-a3b1-665ce339bd39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A01N-10A (Blood Derived Normal), aliquot TCGA-AG-A01N-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06302b6b-8a02-422c-9037-b343828a0796

The open-access MAF lists 115 somatic variants for this specimen: 88 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 23, Nonsense Mutation 8, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, 3'UTR 1, RNA 1, Splice Region 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 32/46 reads (70%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALG5 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1436764338; called by muse, mutect2, varscan2
- ANKRD26 | c.4204C>A p.L1402I | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV65774975, COSV65775956; called by muse, mutect2, varscan2
- APC | c.4476del p.T1493Rfs*14 | Frame Shift Del (DEL) | VAF 100/350 reads (29%) | catalogued as COSV57375363; called by mutect2, varscan2
- AWAT1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs776898049, COSV65738622; called by muse, varscan2
- BLMH | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.181); catalogued as rs1193076586, COSV55586627; called by muse, mutect2, varscan2
- C1orf94 | c.1469C>T p.A490V (on ENST00000488417 / NM_001134734.2; = p.A300V on NM_032884.5) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs760165855, COSV64915426; called by muse, mutect2, varscan2
- CCDC150 | c.3148C>T p.R1050W | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755194723, COSV55875148; called by muse, mutect2, varscan2
- CLRN2 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777976596, COSV72512568; called by muse, mutect2
- COLGALT1 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs148480974; called by muse, mutect2
- CRYBG1 | c.5765G>A p.G1922E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64811873; called by muse, varscan2
- DENND2C | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs779519005, COSV67924337; called by muse, mutect2, varscan2
- DENND4B | c.3928C>T p.R1310W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs765550077; called by muse, mutect2, varscan2
- EXOC8 | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV50478064; called by muse, mutect2
- FSCN3 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs755444623, COSV50000808; called by muse, mutect2, varscan2
- GPBP1L1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1435847227; called by muse, mutect2, varscan2
- GRB14 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs142669508; called by muse, mutect2, varscan2
- IAPP | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs200996235, COSV53714074; called by muse, mutect2, varscan2
- IFNA6 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 367/760 reads (48%) | catalogued as COSV66506644; called by muse, mutect2, varscan2
- IGSF1 | c.825A>G p.I275M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.5); catalogued as COSV100812503; called by muse, mutect2, varscan2
- KLHL8 | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as rs1293865391, COSV56746720; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 78/210 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- KRT80 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as rs767920544; called by muse, mutect2
- LAMB1 | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.122); catalogued as COSV99033478; called by muse, mutect2, varscan2
- LRFN5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs773608812, COSV53260092; called by muse, mutect2, varscan2
- N4BP1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs1389917878, COSV52211189; called by muse, mutect2, varscan2
- NCAN | c.3271G>A p.G1091S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs755391461; called by muse, mutect2, varscan2
- NCR1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766273248, COSV52556187; called by muse, mutect2, varscan2
- NELL1 | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV54284362; called by muse, mutect2
- NPR2 | c.3058C>T p.R1020W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM157841, COSV52414102; called by muse, mutect2, varscan2
- OTX2 | c.809T>G p.F270C (on ENST00000408990 / NM_172337.3; = p.F278C on NM_021728.4) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59766369; called by muse, mutect2, varscan2
- PCDHA6 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1562313135, COSV65344708; called by muse, mutect2, varscan2
- PCDHGA2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1561479324, COSV53963899; called by muse, mutect2, varscan2
- PCSK6 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs372460647; called by muse, mutect2, varscan2
- PEG3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as rs1046467329, COSV55638306; called by muse, mutect2, varscan2
- PGR | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 183/555 reads (33%) | catalogued as COSV54795898, COSV54810645; called by muse, mutect2, varscan2
- PIP5K1A | c.929G>A p.R310H (on ENST00000368888 / NM_001135638.2; = p.R297H on NM_003557.3) | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1242484794, COSV100576480; called by muse, mutect2
- PKN1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV54398857, COSV54404264; called by muse, mutect2, varscan2
- PUM1 | c.2773G>A p.V925I | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs761167558, COSV57085835; called by muse, mutect2, varscan2
- RANBP17 | c.906C>G p.Y302* | Nonsense Mutation (SNP) | VAF 106/470 reads (23%) | catalogued as rs1448052847; called by muse, mutect2, varscan2
- RIPOR3 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs545982151; called by muse, mutect2, varscan2
- RP1 | c.5913C>A p.N1971K | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs754290174, COSV55115958; called by muse, mutect2, varscan2
- RPS6KC1 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 68/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100873852, COSV65300646; called by muse, mutect2, varscan2
- RUNX1T1 | c.1778C>T p.P593L (on ENST00000265814 / NM_001198628.1; = p.P566L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as COSV56143335, COSV56149645; called by muse, mutect2, varscan2
- STX18 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs375534518, COSV104402321; called by muse, mutect2, varscan2
- TAB3 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 183/327 reads (56%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV55837684; called by muse, mutect2, varscan2
- TANC2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67335515; called by mutect2, varscan2
- TENM2 | c.799G>A p.A267T (on ENST00000518659 / NM_001122679.2; = p.A76T on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as rs766686457, COSV69123384; called by muse, mutect2, varscan2
- TNC | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs763289734, COSV60785514; called by muse, mutect2, varscan2
- TNR | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs775102963, COSV54878733; called by muse, mutect2, varscan2
- USP11 | c.1514C>T p.P505L (on ENST00000218348; = p.P462L on NM_001371072.1) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54474039; called by muse, mutect2, varscan2
- ZNF148 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.226); catalogued as rs1455167148; called by muse, mutect2, varscan2
- ZNF391 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs535548914; called by muse, mutect2, varscan2
- ZNF432 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV55417027; called by muse, mutect2, varscan2
- ZW10 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 56/146 reads (38%) | catalogued as COSV52317065; called by muse, mutect2, varscan2
- ABCB5 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 74/411 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACADM | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGAP7P | n.500G>T | Splice Region (SNP) | VAF 11/36 reads (31%) | called by mutect2, varscan2
- APC | c.2563_2564dup p.R856Nfs*6 | Frame Shift Ins (INS) | VAF 94/242 reads (39%) | called by mutect2, varscan2
- CALD1 | c.458dup p.S153Rfs*2 | Frame Shift Ins (INS) | VAF 46/171 reads (27%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.4621C>T p.R1541* | Nonsense Mutation (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2
- CASR | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CCER1 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CEACAM1 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, varscan2
- CIB3 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND2C | c.1486G>A p.V496M (on ENST00000393274 / NM_001256404.2; = p.V439M on NM_198459.4) | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1596T>G p.F532L | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GAS2L3 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.223); called by muse, mutect2
- GPR142 | c.1384G>T p.V462L | Missense Mutation (SNP) | VAF 2/12 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- H3-4 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IQCK | c.750_754del p.K251Hfs*59 | Frame Shift Del (DEL) | VAF 91/283 reads (32%) | called by mutect2, pindel, varscan2
- LGR5 | c.2188A>T p.I730F | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- OR2A7 | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 80/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAK3 | c.646-2A>T p.X216_splice (on ENST00000262836 / NM_001324328.2; = p.X201_splice on NM_002578.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 162/602 reads (27%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4550G>T p.G1517V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RASGRP1 | c.1796T>G p.V599G | Missense Mutation (SNP) | VAF 123/187 reads (66%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM4 | c.1955A>C p.K652T | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- SNX9 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SRP68 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- TENM1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 32/634 reads (5%) | called by muse, mutect2
- TLL1 | c.174_175insG p.F59Vfs*9 | Frame Shift Ins (INS) | VAF 67/155 reads (43%) | called by mutect2, pindel, varscan2
- TULP4 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.8659T>C p.Y2887H | Missense Mutation (SNP) | VAF 33/612 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); called by muse, mutect2
- XIRP2 | c.9083C>T p.T3028I (on ENST00000628543; = p.T3203I on NM_152381.6) | Missense Mutation (SNP) | VAF 146/470 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2318G>A p.W773* | Nonsense Mutation (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.23_42del p.E8Afs*89 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by pindel, varscan2*
- ZXDC | c.1813A>C p.S605R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZXDC | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANO4 | c.2469G>A p.V823= (on ENST00000392977 / NM_001286615.2; = p.V788= on NM_178826.4) | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as COSV54596552; called by muse, mutect2, varscan2
- BRIP1 | c.2232C>T p.D744= | Silent (SNP) | VAF 211/639 reads (33%) | catalogued as rs374362388; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CCPG1 | c.2103T>A p.V701= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV51242182; called by muse, mutect2
- CDH23 | c.5478G>A p.R1826= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV56478777; called by muse, mutect2, varscan2
- CEP350 | c.6279G>A p.Q2093= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV62603871; called by muse, mutect2, varscan2
- DHX30 | c.201C>T p.I67= (on ENST00000445061 / NM_138615.3; = p.I28= on NM_014966.3) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100820047; called by muse, mutect2, varscan2
- DIO2 | c.615G>A p.P205= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV70445289; called by muse, mutect2, varscan2
- DMD | c.1386C>T p.D462= | Silent (SNP) | VAF 107/277 reads (39%) | catalogued as COSV55877407; called by muse, mutect2, varscan2
- FSTL1 | c.921G>A p.E307= | Silent (SNP) | VAF 73/170 reads (43%) | called by muse, mutect2, varscan2
- GBX2 | c.945G>C p.G315= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV60445387; called by muse, varscan2
- HACE1 | c.201C>T p.S67= | Silent (SNP) | VAF 113/330 reads (34%) | called by muse, mutect2, varscan2
- HECTD4 | c.10608T>C p.I3536= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV66393398; called by muse, mutect2
- IKZF3 | c.1275C>T p.Y425= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs765182589, COSV53101138, COSV53102997; called by muse, mutect2, varscan2
- KCNH1 | c.2424G>T p.V808= (on ENST00000271751 / NM_172362.3; = p.V781= on NM_002238.4) | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- KRT28 | c.1092C>A p.T364= | Silent (SNP) | VAF 52/141 reads (37%) | catalogued as rs756835671, COSV100137754; called by muse, mutect2, varscan2
- MYO16 | c.1707C>T p.T569= | Silent (SNP) | VAF 51/102 reads (50%) | catalogued as rs746199612; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXPH4 | c.876G>A p.Q292= | Silent (SNP) | VAF 3/7 reads (43%) | catalogued as COSV61072954; called by mutect2, varscan2
- OR5V1 | c.303T>C p.L101= | Silent (SNP) | VAF 261/637 reads (41%) | catalogued as COSV65828382; called by muse, mutect2, varscan2
- RFTN2 | c.108C>T p.Y36= | Silent (SNP) | VAF 22/329 reads (7%) | catalogued as rs762039291, COSV54386699; called by muse, mutect2
- SEC31A | c.2499C>A p.P833= (on ENST00000355196 / NM_001318120.1; = p.P794= on NM_016211.4) | Silent (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2001C>T p.F667= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs946098801; called by muse, mutect2
- VNN1 | c.372C>T p.L124= | Silent (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.4743T>C p.H1581= | Silent (SNP) | VAF 116/265 reads (44%) | called by muse, mutect2, varscan2
- DCHS2 | n.1846G>A | RNA (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59720826; called by muse, mutect2, varscan2
- LEKR1 | c.*1431G>A | 3'UTR (SNP) | VAF 40/111 reads (36%) | catalogued as COSV62962075; called by muse, mutect2, varscan2
- OSBPL6 | c.987+4562G>A | Intron (SNP) | VAF 18/47 reads (38%) | catalogued as rs113320485, COSV99507207; called by muse, mutect2, varscan2
- TTN | c.34264+5293G>T | Intron (SNP) | VAF 30/74 reads (41%) | catalogued as COSV60114890, COSV60160537; called by muse, mutect2, varscan2
